Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A6F8, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A6F8-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender: M

Location:

Reported:

Ordering MD:

Copy To:

Facility:

Specimen(s) Received

1. Soft-Tissue: LEFT GASTRIC TISSUE
2. paraesophageal fat
3. Esophagus total + proximal stomach with distal proximal resection margins-

Diagnosis

1. "Left gastric tissue":
- portions of adipose tissue, negative for malignancy
2. "Paraesophageal fat":
- negative for malignancy
3. "Esophagus total + proximal stomach with distal proximal resection margins - resection:
- polypoid intramucosal adenocarcinoma of esophagus (T1), well differentiated, arising in a polypoid dysplasia associated with Barrett's esophagus
- foci of high grade dysplasia and additional microscopic foci of intramucosal carcinoma associated with Barrett's esophagus
- proximal resection margin: benign squamous mucosa present; negative for Barrett's mucosa
- distal resection margin: benign gastric body type mucosa
- periesophageal and perigastric lymph nodes x12: negative for malignancy (N0)

CBCE *ICD-O-3*
Adenocarcinoma NOS 8140/3
path
Adenocarcinoma in a polyp
Site: Esophagus, distal third
8/21/13
C15.5
JW 6/10/13

Comment

3. The polypoid tumor is composed of intramucosal adenocarcinoma located mainly in the tip and arising in the setting of a polypoid dysplasia. There is no invasion into the submucosa. The surrounding mucosa shows features of Barrett's mucosa with high grade dysplasia and additional microscopic foci of intramucosal carcinoma.

Electronically verified by:

[page 2 of 2]
Surgical Pathology Consultation Report

Clinical History

ESOPHAGEAL CANCER

Gross Description

1. The specimen container labeled with the patient's name and as "left gastric tissue", contains one piece of grey yellow adipose tissue measuring 5.0 x 2.5 x 0.3 cm received in 10% buffered formalin. On palpating it is grossly unremarkable. 1A-1B representative sections submitted in toto.

2. The specimen container labeled with the patient's name and as "paraesophageal fat", contains one piece of fatty tissue measuring 12.0 x 2.0 x 1.1 cm received in 10% buffered formalin. On palpating no nodes are identified. 2A-2C representative sections submitted in toto.

3. The specimen container labeled with the patient's name and as "esophagus total and proximal stomach with distal proximal resection margins" contains a section of esophagus with proximal portion of stomach attached in the fresh state. The esophagus measures 11.0 cm in length and the proximal open stomach measures 8.5 x 0.5 cm. The diameter of the proximal resection margin esophageal margin is 2.1 cm. The diameter of the distal stomach resection margin is 12.0 cm. There is a superficial polypoid lesion in the esophagus measuring 3.1 cm in length x 1.5 cm in diameter in the fixed state. The base of the polyp measures 1.7 cm in fixed state. The polyp is 8.5 cm from the proximal resection margin and 5.0 cm from the closest distal resection margin. Extending from the esophageal junction is a tan flat granular mucosa surrounding the polypoid tumor. This tan area measures between 2.5 and 4.5 cm in height. The remaining esophageal mucosa and stomach mucosa appear grossly unremarkable. A piece of tumoral tissue and piece of esophageal mucosa is taken for tissue frozen. Intraoperative consultation performed on a frozen of the distal resection margin and proximal resection margin. Along with other sections of the specimen the polyp has been submitted in toto. Sections are submitted as follows:

3A-3B distal margin frozen section en face

3C esophageal resection margin. frozen section en face

3D perpendicular section of the distal resection margin

3E-3G polypoid tissue

3I the rest of the polyp

3J-3L adjacent granular mucosa on one side of the tumor

3M adjacent longitudinal section of the granular mucosa on the other side of the tumor

3N one representative section of the gastroesophageal junction.

3O transverse section of the upper esophagus

3P random section of stomach mucosa

3Q largest gastric esophageal node, measuring 1.8 x 0.7 x 0.5 cm.

3R-3T more nodes from the periesophageal gastric region, 3 nodes in 3R, 2 nodes in 3S, four nodes in 3T.

Quick Section Diagnosis

3A-3B Distal gastric margin - "Negative for malignancy"

3C - Esophageal proximal margin - "Negative for malignancy"

Source: NCI Genomic Data Commons file 205404e7-efb4-488f-8b86-523803253f8f (TCGA-JY-A6F8.85F7C2C1-4EFC-451E-B4F2-5287DB044543.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).